Somatic mutation profile of tumor specimen 0DJ6KK from CCDI case PBBWDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 3.6 years (1,313 days).
Specimen 0DJ6KK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbae235d-e0e7-4298-a804-c3ad017ad6de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97650838-5752-4257-9bc3-f052057498ee

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC2 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 401/1032 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs753583620, COSV55339730; called by muse, mutect2, varscan2
- OR4A47 | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 325/858 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs578151672; called by muse, mutect2, varscan2
- KCNJ2 | c.475T>A p.F159I | Missense Mutation (SNP) | VAF 84/812 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LSMEM1 | c.114_115del p.Q39Afs*55 | Frame Shift Del (DEL) | VAF 157/576 reads (27%) | called by mutect2, varscan2
- ADAMTS10 | c.-93G>A | 5'UTR (SNP) | VAF 38/97 reads (39%) | catalogued as rs930559394; called by muse, mutect2, varscan2
